Somatic mutation profile of tumor specimen TCGA-AD-6963-01A (aliquot TCGA-AD-6963-01A-11D-1924-10) from TCGA case TCGA-AD-6963, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; Age at diagnosis: 58.3 years (21,294 days).
Specimen TCGA-AD-6963-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 044bf538-094d-4a6f-96f2-9d6bafac46f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-6963-10A (Blood Derived Normal), aliquot TCGA-AD-6963-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee227d21-526a-47d1-aedc-e0462267af40

The open-access MAF lists 78 somatic variants for this specimen: 56 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 19, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3577C>T p.Q1193* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as rs1554085128, CD961774, CM931179, COSV57340826; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.695T>G p.I232S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs587781589, CM103212, COSV52661257, COSV52760307, COSV52829354; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AL121899.2 | c.1993G>A p.V665M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.296); catalogued as rs760313314, COSV67350553; called by muse, mutect2, varscan2
- ATM | c.5170G>C p.E1724Q | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.513); catalogued as COSV53736936, COSV99591641; called by muse, mutect2, varscan2
- ATP10A | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV63514179; called by muse, mutect2
- CCNA1 | c.64T>A p.Y22N | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV55221333; called by muse, mutect2, varscan2
- CDK11B | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1277215727, COSV58338340; called by muse, mutect2, varscan2
- CEP170 | c.3902A>T p.E1301V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60508802; called by muse, varscan2
- COL11A1 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV62182816; called by muse, mutect2, varscan2
- CR1 | c.2620C>A p.P874T | Missense Mutation (SNP) | VAF 37/464 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65458094; called by muse, mutect2
- DDR2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759709680, COSV63370740, COSV63375402; called by muse, mutect2, varscan2
- DNAAF2 | c.1609C>G p.L537V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV53569220; called by muse, mutect2, varscan2
- DNAH1 | c.5882C>T p.T1961M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs996417850, COSV70228746; called by muse, mutect2, varscan2
- DNAH11 | c.757C>G p.Q253E | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs772084560, COSV100180567; called by muse, mutect2, varscan2
- DNAH3 | c.2429G>A p.R810H | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.068); catalogued as rs1189581952, COSV54542910; called by muse, mutect2, varscan2
- EXT1 | c.2146C>A p.P716T | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65475234, COSV65479168; called by muse, mutect2, varscan2
- FAF1 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100876073; called by muse, mutect2
- FLNC | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as rs367997079; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GARRE1 | c.1055A>G p.K352R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.011); catalogued as COSV55099043; called by muse, mutect2
- HCFC1 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV60072036; called by muse, mutect2, varscan2
- KIRREL1 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1246209558, COSV100780124; called by muse, mutect2
- KRTAP9-3 | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.631); catalogued as rs747778232, COSV68616504; called by muse, mutect2, varscan2
- LPAR6 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV57298616; called by muse, mutect2
- MAGEC3 | c.1667T>A p.I556N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53579816; called by muse, mutect2, varscan2
- MIS18BP1 | c.2514del p.V839Sfs*20 | Frame Shift Del (DEL) | VAF 17/127 reads (13%) | catalogued as rs1566809875; called by mutect2, pindel, varscan2
- MYT1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs977126432, COSV60503934; called by muse, mutect2, varscan2
- NBEAL1 | c.6597C>G p.I2199M | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68916024; called by muse, mutect2, varscan2
- NDUFA13 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs560580344, COSV53063553, COSV99388857; called by muse, mutect2, varscan2
- NRXN3 | c.2374G>A p.V792M (on ENST00000335750 / NM_001330195.2; = p.V419M on NM_004796.6) | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1478473675, COSV59745379; called by muse, mutect2, varscan2
- NSRP1 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as COSV55933841; called by muse, mutect2, varscan2
- NSUN5 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53091602; called by muse, mutect2, varscan2
- OR4C13 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV73648743; called by muse, mutect2, varscan2
- OR6B3 | c.196A>C p.M66L | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60113899; called by muse, mutect2
- P3H3 | c.1331A>G p.K444R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99301624; called by muse, mutect2, varscan2
- PHACTR1 | c.1392G>A p.R464= | Splice Region (SNP) | VAF 16/124 reads (13%) | catalogued as rs775859738, COSV60666040; called by muse, mutect2, varscan2
- POLB | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55346506; called by muse, mutect2
- PWWP3B | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV61799570; called by muse, mutect2, varscan2
- RAB17 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52815730; called by muse, mutect2, varscan2
- RASGRP2 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs771246989, COSV62449060; called by muse, mutect2, varscan2
- RTKN2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs758667603, COSV104408833, COSV59521679; called by muse, mutect2, varscan2
- RUNX1T1 | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.152); catalogued as COSV56146011; called by muse, mutect2, varscan2
- SACS | c.13220G>T p.S4407I | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.542); catalogued as COSV66539453; called by muse, mutect2, varscan2
- SCN5A | c.3350A>T p.Q1117L (on ENST00000333535 / NM_198056.3; = p.Q1116L on NM_000335.5) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as COSV61123445; called by muse, mutect2, varscan2
- SIPA1L2 | c.4723G>C p.D1575H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53389959; called by muse, mutect2, varscan2
- SLC25A6 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV58430694, COSV58431125; called by muse, mutect2
- SRRM3 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs782810649, COSV100418747; called by muse, mutect2, varscan2
- TECTA | c.5440T>C p.S1814P | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99881346; called by muse, mutect2, varscan2
- TMEM154 | c.131C>G p.T44S | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV58590601; called by muse, mutect2, varscan2
- TMEM254 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as rs777639712, COSV64845758; called by muse, mutect2, varscan2
- TRPC6 | c.536C>A p.A179E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV60254341; called by muse, mutect2, varscan2
- TUBA1B | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.821); catalogued as COSV60136951; called by muse, mutect2, varscan2
- UBASH3B | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757968710, COSV52494372; called by muse, mutect2, varscan2
- ZNF648 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as rs368688153, COSV60570798; called by muse, mutect2, varscan2
- ANK3 | c.2881dup p.R961Kfs*27 (on ENST00000280772 / NM_001320874.2; = p.R95Kfs*27 on NM_001149.3) | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- SUPT20HL2 | c.1421T>C p.I474T | Missense Mutation (SNP) | VAF 65/319 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1149_1150del p.C383Wfs*52 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | called by pindel, varscan2
- ALDH8A1 | c.231G>A p.A77= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs568113669, COSV55641668; called by muse, mutect2, varscan2
- CANX | c.657T>C p.A219= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as COSV56004128; called by muse, mutect2, varscan2
- CNTN5 | c.2142G>T p.L714= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1294059665, COSV54308434; called by muse, mutect2, varscan2
- CTSC | c.1293C>A p.T431= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV57057734; called by muse, mutect2, varscan2
- DEAF1 | c.498G>T p.P166= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV58606965; called by muse, mutect2
- GALNTL6 | c.465A>T p.S155= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as COSV71828166; called by muse, mutect2
- GRPR | c.84C>G p.L28= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV66669290; called by muse, mutect2, varscan2
- KRT35 | c.327C>T p.A109= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs768826142, COSV55842997; called by muse, mutect2, varscan2
- NRP1 | c.270C>T p.F90= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs764061468, COSV55166172; called by muse, mutect2
- OFD1 | c.3003A>T p.T1001= | Silent (SNP) | VAF 55/230 reads (24%) | catalogued as COSV57422365; called by muse, mutect2, varscan2
- OR2T5 | c.126G>A p.A42= | Silent (SNP) | VAF 30/306 reads (10%) | catalogued as rs772961885, COSV63540775, COSV63540848; called by muse, mutect2
- OR52N4 | c.774C>T p.F258= | Silent (SNP) | VAF 51/194 reads (26%) | catalogued as COSV57891005; called by muse, mutect2, varscan2
- OSMR | c.1515C>T p.C505= | Silent (SNP) | VAF 35/212 reads (17%) | catalogued as rs367714483; called by muse, mutect2, varscan2
- PCDH9 | c.2493C>T p.F831= | Silent (SNP) | VAF 21/191 reads (11%) | catalogued as rs775323783, COSV60530389, COSV60543623; called by muse, mutect2, varscan2
- RUNX2 | c.1380G>A p.P460= (on ENST00000371438; = p.P438= on NM_001015051.3) | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs756718952, COSV61840797; called by muse, mutect2, varscan2
- TELO2 | c.138G>A p.A46= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs780539371, COSV51977522; called by mutect2, varscan2
- TMCC2 | c.783C>T p.P261= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs201946978, COSV58003090; called by muse, mutect2, varscan2
- TTN | c.78054T>A p.T26018= (on ENST00000591111; = p.T18594= on NM_003319.4) | Silent (SNP) | VAF 25/190 reads (13%) | catalogued as COSV100627219; called by muse, mutect2, varscan2
- ZNF688 | c.711C>T p.S237= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1389839493, COSV56300665; called by muse, mutect2, varscan2
- CCDC33 | c.1938+385G>A | Intron (SNP) | VAF 7/41 reads (17%) | catalogued as rs374939337, COSV51431961; called by muse, mutect2, varscan2
- MIF | c.-2T>G | 5'UTR (SNP) | VAF 30/77 reads (39%) | catalogued as COSV99303636; called by muse, mutect2, varscan2
- MIR379 | n.64C>A | RNA (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
